Somatic mutation profile of tumor specimen TCGA-XM-A8RD-01A (aliquot TCGA-XM-A8RD-01A-11D-A423-09) from TCGA case TCGA-XM-A8RD, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 69.5 years (25,402 days).
Specimen TCGA-XM-A8RD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efcda24d-e847-4660-bf8b-0594e677d700.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XM-A8RD-10A (Blood Derived Normal), aliquot TCGA-XM-A8RD-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cc5416d-ef9e-44dd-b451-8bf815eaba1a

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC6A19 | c.1651G>T p.V551L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.434); called by mutect2, varscan2
- TMC2 | c.66C>T p.S22= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs545151967; called by mutect2, varscan2
